Surgical pathology report (de-identified scan), TCGA case TCGA-5C-AAPD, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Cureline, specimen TCGA-5C-AAPD-01A (Primary Tumor).

Case #

Patient: Age (years): Gender: Male

Clinical diagnosis: Primary liver cancer

Date of procurement:

Sample:

Gross description: left lobe of the liver and intrahepatic bile duct. Section shows gray color mass with necrotic nests, there is no infiltration of the liver capsule. Section shows dense consistency cyanotic color.

Microscopic description: Section shows mix of cholangiocarcinoma and hepatocellular carcinoma with mostly fibrous stroma. Stroma is not very cellular. Consistence with poorly differentiated ductal hepatocellular cancer (G1) Lymphatic nodes show no signs of tumor growth.

Final diagnosis: Primary liver cancer.

ICD-O-3
Cholangiocarcinoma & hepatocellular
carcinoma, combined 8180/3
Site: Liver C22.0
JAH/22/14

Confidential

Source: NCI Genomic Data Commons file 2ef45a7b-dd1a-48b6-aaca-bf9f32f4e51e (TCGA-5C-AAPD.E4DB31C4-89F3-4D8D-A32E-B42C599904E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).